Gene-level copy-number profile of tumor specimen C3N-01196-04 from CPTAC case C3N-01196, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.2 years (24,546 days).
Specimen C3N-01196-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e80f5b8-b915-4a8c-af28-569f7fb5525e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01196-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/884d9d8e-78fd-4c31-b21c-ec51ec3685f3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 12,156; copy number 2: 36,511; copy number 3: 10,114; copy number 4: 4; copy number 5: 1; copy number 18: 1; copy number 31: 3; copy number 33: 31; copy number 34: 10; copy number 37: 4; copy number 46: 17; copy number 47: 19; copy number 48: 3.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:45,676,369–46,710,886, 33 genes (within-gene range 0–2): LIMD1-AS1, SACM1L, RN7SL145P, AC098476.1, SLC6A20, LZTFL1, AC099782.1, SDHDP4, CCR9, Y_RNA, FYCO1, CXCR6, XCR1, NRBF2P2, FLT1P1, CCR3, CCR1, UQCRC2P1, CCR2, CCR5AS, CCR5, CCRL2, LTF, RTP3, LRRC2, LRRC2-AS1, TDGF1, AC104304.2, FAM240A, AC104304.3, AC104304.1, ALS2CL, TMIE.
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–1): PRSS46P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,542,325–56,568,858, 71 genes, copy number 18–48 (broad region; genes not listed).
- chr17:7,217,125–7,239,722, 4 genes, copy number 37: ACADVL, MIR324, DVL2, PHF23.
- chr17:78,356,778–78,782,297, 13 genes, copy number 33: SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1, DNAH17, DNAH17-AS1, AC016182.1, RN7SL454P, SCAT1, CYTH1, AC099804.1, RNU6-638P.
- chr21:8,603,547–8,603,984, 1 gene, copy number 5: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 9,815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
